Somatic mutation profile of tumor specimen MP2PRT-PASYSF-TMP1-B (aliquot MP2PRT-PASYSF-TMP1-B-1-0-D-A817-36) from MP2PRT case MP2PRT-PASYSF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.0 years (1,824 days).
Specimen MP2PRT-PASYSF-TMP1-B: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9d49eff-876a-4604-b583-9695fd353407.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASYSF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASYSF-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b729a8f-8cbd-4a82-95ba-2b45402111d8

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 12, Silent 5, Nonsense Mutation 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH1L2 | c.2152G>T p.G718* | Nonsense Mutation (SNP) | VAF 107/331 reads (32%) | catalogued as COSV51556259; called by muse, mutect2, varscan2
- CACNA1D | c.5840C>T p.T1947M (on ENST00000350061 / NM_001128840.3; = p.T1967M on NM_000720.4) | Missense Mutation (SNP) | VAF 30/533 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as rs752102016, COSV55452349; called by muse, mutect2
- EP300 | c.5380A>T p.K1794* | Nonsense Mutation (SNP) | VAF 240/574 reads (42%) | catalogued as COSV54329723; called by muse, mutect2, varscan2
- EYS | c.2992G>T p.G998C | Missense Mutation (SNP) | VAF 22/343 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65559813; called by muse, mutect2
- F13B | c.279G>T p.K93N | Missense Mutation (SNP) | VAF 76/225 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV66373897; called by muse, mutect2, varscan2
- INSR | c.2981C>T p.S994F | Missense Mutation (SNP) | VAF 16/366 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57173643; called by muse, mutect2
- MYO1F | c.2954C>T p.P985L | Missense Mutation (SNP) | VAF 50/698 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs570160376, COSV100596329; called by muse, mutect2
- PHEX | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 130/374 reads (35%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.871); catalogued as rs1057515843; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPDC1 | c.1999C>T p.R667* (on ENST00000375360 / NM_177995.3; = p.R719* on NM_152422.4) | Nonsense Mutation (SNP) | VAF 24/490 reads (5%) | catalogued as rs1055915999, COSV56624665; called by muse, mutect2
- ANKRD24 | c.2228C>T p.A743V | Missense Mutation (SNP) | VAF 387/876 reads (44%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- GPRASP1 | c.514A>G p.M172V | Missense Mutation (SNP) | VAF 220/603 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGKV1D-16 | chr2:90100737 ins TT | Frame Shift Ins (INS) | VAF 84/277 reads (30%) | called by mutect2, varscan2
- NR3C1 | c.1324A>G p.K442E | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2
- PCDHB12 | c.539T>C p.V180A | Missense Mutation (SNP) | VAF 21/216 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- XIRP2 | c.5195A>G p.N1732S (on ENST00000628543; = p.N1907S on NM_152381.6) | Missense Mutation (SNP) | VAF 91/232 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZNF724 | c.651G>C p.K217N | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); called by muse, mutect2
- CYLC1 | c.1605T>A p.S535= | Silent (SNP) | VAF 132/322 reads (41%) | called by muse, mutect2, varscan2
- KCNT1 | c.1875G>A p.K625= (on ENST00000488444; = p.K644= on NM_020822.3) | Silent (SNP) | VAF 242/587 reads (41%) | called by muse, mutect2, varscan2
- MED13 | c.5124C>G p.P1708= | Silent (SNP) | VAF 191/398 reads (48%) | called by muse, mutect2, varscan2
- NEMF | c.621C>T p.F207= | Silent (SNP) | VAF 70/248 reads (28%) | catalogued as rs770219251; called by muse, mutect2, varscan2
- RNF112 | c.702G>T p.L234= | Silent (SNP) | VAF 171/417 reads (41%) | called by muse, mutect2, varscan2
